FM case AD7513 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Trachea.
https://portal.gdc.cancer.gov/cases/ca4ae58f-b445-47ad-8c7e-af6568b91960

Male, 68.8 years: Adenoid cystic carcinoma (ICD-O-3 8200/3) of the trachea; metastasis biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
